TCGA case TCGA-JY-A6FB — Esophageal Carcinoma (TCGA-ESCA)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Esophagus; Tissue source site: University Health Network. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/c17331fb-c47b-40b5-8d39-9803ee37a42a

Demographics
Sex at birth: male; Race: white; Country of residence at enrollment: Canada; Age at index: 77 years; Vital status: Alive.

Diagnoses (2)
1. Adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8140/3; ICD-10 code: C15.5; Tissue or organ of origin: Lower third of esophagus; Site of resection or biopsy: Esophagus, NOS; Classification of tumor: primary; Age at diagnosis: 77.4 years (28,269 days); Year of diagnosis: 2007; Method of diagnosis: Biopsy; AJCC staging edition: 6th; AJCC pathologic T: T1; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage I; Tumor grade: G2; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 1,837 days (5.0 years); Esophageal columnar dysplasia degree: High Grade Dysplasia; Esophageal columnar metaplasia present: Yes; Goblet cells columnar mucosa present: No; Sites of involvement: Esophagus, Lower Third.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 0; Lymph nodes tested: 24.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.
2. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Prostate gland; Classification of tumor: Prior primary; Age at diagnosis: 66.4 years (24,259 days); Days to diagnosis: -4,010 days (-11.0 years).
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.

Follow-up (2 entries)
- Days to follow up: 1,837 days (5.0 years); Disease response: Tumor Free.
- Barretts esophagus goblet cells present: No; Timepoint: Prior to Diagnosis.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Comorbidities: Barrett's Esophagus; Risk factors: Barrett's Esophagus.
- Timepoint category: Initial Diagnosis; Weight: 95 kg; Height: 177 cm; BMI: 30.3.

Exposures
- Alcohol history: No; Alcohol drinks per day: 0; Alcohol days per week: 0.
- Exposure type: Tobacco; Tobacco smoking status: Lifelong Non-Smoker.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-JY-A6FB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 100 mg.
  Slide TCGA-JY-A6FB-01A-01-TS1: Section location: Top; Percent tumor cells: 70; Percent tumor nuclei: 90; Percent normal cells: 20; Percent necrosis: 0; Percent stromal cells: 10; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-JY-A6FB-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-JY-A6FB-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; Cancer procurement state province: Ontario; Cancer procurement city: Toronto; History neoadjuvant treatment: No; Tumor status: Tumor free; Tobacco smoking history indicator: 1; Alcohol history documented: Yes; Alcohol consumption frequency: 0; History hpylori infection indicator: Never; History barretts esophageal indicator: Yes-USA; New tumor event diagnosis indicator: No.
- Primary pathology: Esophageal tumor location centered: Distal; Histologic diagnosis: Esophagus Adenocarcinoma, NOS; Method initial path diagnosis: Endoscopic Biopsy; Lymph nodes examined: Yes.
- Primary pathology, Esophageal tumor involvement sites: Esophageal tumor location involved: Distal.
- Follow-up form: Lost to follow-up: No; Tumor status: Tumor free; Treatment outcome first course: Complete Remission/Response; Treatment outcome at TCGA followup: Complete Response; New tumor event diagnosis indicator: No.
- Other malignancy form: Malignancy type: Prior Malignancy; Other malignancy anatomic site: Prostate; Other malignancy histological type: Adenocarcinoma, Not Otherwise Specified.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,837 days; disease-specific survival: no event (censored), 1,837 days; disease-free interval: no event (censored), 1,837 days; progression-free interval: no event (censored), 1,837 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-JY-A6FB-01A-11D-A33D-01): tumor purity 0.64, ploidy 2.88, whole-genome doublings 1.
